Somatic mutation profile of tumor specimen TCGA-06-0187-01A (aliquot TCGA-06-0187-01A-01D-1491-08) from TCGA case TCGA-06-0187, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.3 years (25,318 days).
Specimen TCGA-06-0187-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a84b6cac-6354-4348-a1f1-fbef306c109c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0187-10B (Blood Derived Normal), aliquot TCGA-06-0187-10B-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9371b8de-e9b6-4392-b1dd-bc85a5881cb5

The open-access MAF lists 43 somatic variants for this specimen: 33 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 8, Splice Site 2, RNA 1, Nonsense Mutation 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PGAP1 | c.927+1G>A p.X309_splice | Splice Site (SNP) | VAF 11/43 reads (26%) | catalogued as rs750079325, COSV100698282; ClinVar: pathogenic; called by muse, varscan2
- PTEN | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 102/168 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs121909241, CM045431, CM063078, CM074468, COSV64288421, COSV64288528, COSV64293854; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- ARAP2 | c.36A>C p.K12N | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.174); catalogued as COSV100394922, COSV58286147; called by muse, varscan2
- BNC1 | c.1804T>G p.F602V | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100597334; called by muse, mutect2, varscan2
- BNC2 | c.2652C>A p.N884K | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV101036517; called by muse, mutect2, varscan2
- CD55 | c.1060+2T>C p.X354_splice | Splice Site (SNP) | VAF 42/105 reads (40%) | catalogued as COSV100132532; called by muse, mutect2, varscan2
- CFAP47 | c.910G>T p.D304Y | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV52893454; called by muse, mutect2, varscan2
- CREB3L3 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs372070326, COSV50215787; called by muse, mutect2, varscan2
- DNAH5 | c.13476A>T p.L4492F | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99451695; called by muse, mutect2, varscan2
- ELSPBP1 | c.596A>G p.E199G | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.3); catalogued as COSV100353691; called by muse, mutect2, varscan2
- GALNT17 | c.1454A>T p.E485V | Missense Mutation (SNP) | VAF 109/553 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); catalogued as COSV100354686; called by muse, mutect2, varscan2
- GEMIN4 | c.2543T>G p.L848R | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100021467; called by muse, mutect2, varscan2
- GPR6 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 95/145 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV51572250; called by muse, mutect2, varscan2
- GRM3 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV64466818; called by muse, mutect2, varscan2
- LPAR1 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs770286316, COSV100730935; called by muse, mutect2, varscan2
- NEU2 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0.119); catalogued as rs552601468, COSV52094636; called by muse, mutect2, varscan2
- OR2J2 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs779291311, COSV101013411; called by muse, mutect2, varscan2
- OR52B2 | c.788C>G p.T263S | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101603956; called by muse, mutect2, varscan2
- PCDHA12 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 104/249 reads (42%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as COSV56523218; called by muse, mutect2, varscan2
- PKHD1 | c.7547T>C p.F2516S | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100583747; called by muse, mutect2, varscan2
- PLAT | c.1210_1212del p.D404del | In Frame Del (DEL) | VAF 61/219 reads (28%) | catalogued as rs1220509193; called by mutect2, pindel, varscan2
- PLIN5 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV67850653; called by muse, mutect2, varscan2
- PMVK | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 176/458 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs959646389, COSV100870520; called by muse, mutect2, varscan2
- RFPL2 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 82/186 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.107); catalogued as rs1379803837, COSV99964399; called by muse, mutect2, varscan2
- RNASE6 | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 100/241 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100485942; called by muse, mutect2, varscan2
- RUNDC1 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs562961994, COSV100799368; called by muse, varscan2
- SAMD14 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs780108620, COSV50305385; called by muse, mutect2, varscan2
- SLC25A52 | c.58A>T p.R20W (on ENST00000672005; = p.R10W on NM_001034172.4) | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV99329687; called by muse, mutect2, varscan2
- SULT1B1 | c.843T>A p.Y281* | Nonsense Mutation (SNP) | VAF 61/164 reads (37%) | catalogued as COSV100150364; called by muse, mutect2, varscan2
- SYT16 | c.1211C>T p.T404M | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748935569, COSV70856401; called by muse, mutect2, varscan2
- TBX3 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.196); catalogued as rs765693432, COSV57468979; called by muse, mutect2, varscan2
- TSHZ2 | c.1911T>A p.S637R | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as COSV100296413; called by muse, mutect2, varscan2
- NEDD4L | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2
- OR5F1 | c.417C>A p.T139= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as rs201523946, COSV53546357, COSV99558312; called by muse, mutect2, varscan2
- SH3PXD2B | c.1704C>T p.H568= | Silent (SNP) | VAF 89/245 reads (36%) | catalogued as rs142812825; called by muse, mutect2, varscan2
- SUPT6H | c.5157A>G p.P1719= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as COSV99972846; called by muse, mutect2, varscan2
- TEX11 | c.2229C>T p.Y743= (on ENST00000344304; = p.Y728= on NM_031276.3) | Silent (SNP) | VAF 26/28 reads (93%) | catalogued as rs747561868, COSV100721974; called by muse, mutect2, varscan2
- TNFRSF11B | c.481A>C p.R161= | Silent (SNP) | VAF 75/169 reads (44%) | catalogued as COSV52074333, COSV99816791; called by muse, mutect2, varscan2
- UGT2B4 | c.534C>T p.Y178= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as rs370531105; called by muse, mutect2, varscan2
- ZNF235 | c.2085C>T p.A695= | Silent (SNP) | VAF 58/132 reads (44%) | catalogued as rs1453195808, COSV99349580; called by muse, mutect2, varscan2
- ZNF91 | c.1848C>T p.T616= | Silent (SNP) | VAF 45/143 reads (31%) | catalogued as COSV56082504; called by muse, mutect2, varscan2
- NBPF25P | n.856G>A | RNA (SNP) | VAF 55/318 reads (17%) | catalogued as rs1332852823; called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331275 G>A | 5'Flank (SNP) | VAF 36/118 reads (31%) | called by muse, mutect2, varscan2
